Somatic mutation profile of tumor specimen TCGA-CQ-7072-01A (aliquot TCGA-CQ-7072-01A-21D-A30E-08) from TCGA case TCGA-CQ-7072, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 51.6 years (18,841 days).
Specimen TCGA-CQ-7072-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9dbd4c1b-5677-4928-a43e-7fe76e393228.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-7072-10A (Blood Derived Normal), aliquot TCGA-CQ-7072-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a7e3be6-ff03-453c-b928-3d7bfde377b5

The open-access MAF lists 122 somatic variants for this specimen: 106 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 95, Silent 16, Splice Site 4, Nonsense Mutation 4, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 55/89 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.5486A>G p.D1829G (on ENST00000272895 / NM_173076.3; = p.D1511G on NM_015657.3) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99790136; called by muse, mutect2, varscan2
- AC004593.2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs1454857779, COSV99765162; called by muse, mutect2, varscan2
- ACOXL | c.1570C>T p.R524W (on ENST00000389811 / NM_001371254.1; = p.R494W on NM_001142807.4) | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs773104700, COSV67736418; called by muse, mutect2, varscan2
- AKAP9 | c.5078G>T p.G1693V | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs772261950, COSV100662434; called by muse, mutect2, varscan2
- ALDH3A2 | c.683G>T p.R228L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM122178, COSV51568615, COSV99449933; called by muse, mutect2, varscan2
- ASAP1 | c.818A>G p.Y273C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.785); catalogued as rs1260998937, COSV63052894; called by muse, mutect2, varscan2
- ATG2B | c.3334T>C p.S1112P | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV100738042; called by muse, mutect2, varscan2
- BCKDK | c.545A>T p.D182V | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as COSV99570648; called by muse, mutect2, varscan2
- BRF1 | c.1830G>T p.L610F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100527356; called by muse, mutect2
- CCDC89 | c.447G>T p.K149N | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as COSV100320859; called by muse, mutect2, varscan2
- CCT8L2 | c.1646C>T p.T549I | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100742778; called by muse, mutect2, varscan2
- CEP112 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV101210400, COSV101210767; called by muse, mutect2, varscan2
- CKLF-CMTM1 | c.186A>T p.L62F | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99862597; called by muse, mutect2, varscan2
- CNTNAP5 | c.1775A>T p.E592V | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101443598; called by muse, mutect2, varscan2
- CR1L | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as CM142353, COSV99687423; called by muse, mutect2, varscan2
- DIPK2A | c.1004A>T p.D335V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV100237293; called by muse, mutect2, varscan2
- DNMT1 | c.4054A>G p.S1352G | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as COSV100532511; called by muse, mutect2, varscan2
- DSCAM | c.4753G>T p.E1585* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV101260271; called by muse, mutect2, varscan2
- DSG1 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99936050; called by muse, mutect2, varscan2
- EPB41L2 | c.2894A>T p.D965V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100440790; called by mutect2, varscan2
- ERBB3 | c.644A>G p.N215S | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as rs1256589883, COSV99916926; called by muse, mutect2, varscan2
- EZH1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768296055, COSV70550780; called by muse, mutect2, varscan2
- F5 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as COSV100889118; called by muse, mutect2, varscan2
- FAT3 | c.2102A>C p.K701T | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); catalogued as COSV99966490; called by muse, mutect2, varscan2
- HECTD1 | c.5150G>T p.G1717V | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.108); catalogued as COSV101237399; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100676500; called by muse, mutect2, varscan2
- IFT140 | c.4277G>A p.G1426E | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs886051708, COSV99248379; ClinVar: uncertain significance; called by muse, mutect2
- IFT43 | c.173G>A p.C58Y | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.422); catalogued as COSV99466149; called by muse, mutect2, varscan2
- IQUB | c.422G>C p.G141A | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100227135; called by muse, mutect2, varscan2
- IRX4 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99180800; called by muse, mutect2, varscan2
- ISYNA1 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1465407688, COSV99526102; called by muse, mutect2, varscan2
- KDM3B | c.3433C>A p.Q1145K | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV100069665; called by muse, mutect2, varscan2
- KHDRBS1 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV56981620; called by muse, mutect2, varscan2
- KIF21A | c.1216-1G>T p.X406_splice | Splice Site (SNP) | VAF 14/55 reads (25%) | catalogued as COSV62779855; called by muse, mutect2, varscan2
- KIF5C | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.308); catalogued as rs754743758, COSV101276145; called by muse, mutect2, varscan2
- KLHL1 | c.1981A>T p.N661Y | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV100917346; called by muse, mutect2, varscan2
- KRTAP10-9 | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 142/414 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as COSV59956526, COSV59980912; called by muse, mutect2, varscan2
- LENG8 | c.1834-2A>G p.X612_splice | Splice Site (SNP) | VAF 28/100 reads (28%) | catalogued as COSV100418080; called by muse, mutect2, varscan2
- LENG9 | c.813A>T p.E271D | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV100002814; called by muse, mutect2, varscan2
- LMX1A | c.476G>A p.S159N | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs909234124, COSV99672326; called by muse, mutect2
- LRP12 | c.1360G>A p.G454R | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV99407780; called by muse, mutect2, varscan2
- LRRC37A3 | c.3728C>T p.A1243V | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); catalogued as COSV100141044; called by muse, mutect2, varscan2
- MAGEB1 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0.348); catalogued as rs201687675, COSV100974987; called by muse, mutect2, varscan2
- MAGEE2 | c.42G>C p.E14D | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV100973087; called by muse, mutect2, varscan2
- MOGAT2 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as COSV99549571; called by muse, mutect2, varscan2
- MYCBP2 | c.3611G>A p.G1204E (on ENST00000357337; = p.G1242E on NM_015057.5) | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100630455; called by muse, mutect2, varscan2
- MYH4 | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV55121989, COSV99701336; called by muse, mutect2, varscan2
- MYL4 | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.943); catalogued as rs1183246362, COSV100733120; called by muse, mutect2, varscan2
- NAV3 | c.2635A>T p.S879C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV99891390; called by muse, mutect2, varscan2
- NEK8 | c.1892-1G>A p.X631_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99261926; called by muse, mutect2, varscan2
- NINL | c.3310C>T p.R1104W | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs893257630, COSV99625409; called by muse, mutect2, varscan2
- NRBP1 | c.567-2A>T p.X189_splice | Splice Site (SNP) | VAF 12/75 reads (16%) | catalogued as COSV99275044; called by muse, mutect2, varscan2
- NRG3 | c.640G>T p.G214* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100931562; called by muse, mutect2, varscan2
- NSD1 | c.2035C>T p.Q679* | Nonsense Mutation (SNP) | VAF 14/88 reads (16%) | catalogued as COSV100729160; called by muse, mutect2, varscan2
- NTSR2 | c.874C>T p.L292F | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100183915, COSV100184042; called by muse, mutect2, varscan2
- NUDT7 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.657); catalogued as rs541244539, COSV99216088; called by muse, mutect2, varscan2
- OR13D1 | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV100598689; called by muse, mutect2, varscan2
- OR4A15 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1338978608, COSV100124112; called by muse, mutect2, varscan2
- ORC4 | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV51574276, COSV99932259; called by muse, mutect2, varscan2
- OSBPL2 | c.680A>G p.N227S (on ENST00000313733 / NM_144498.4; = p.N215S on NM_014835.4) | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV100569271; called by muse, mutect2, varscan2
- PCDH11X | c.3789G>T p.Q1263H | Missense Mutation (SNP) | VAF 86/155 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); catalogued as COSV100011917; called by muse, mutect2, varscan2
- PCLO | c.14753C>A p.A4918D | Missense Mutation (SNP) | VAF 87/224 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100433098; called by muse, mutect2, varscan2
- PEX3 | c.1085A>C p.Y362S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100852155; called by muse, mutect2, varscan2
- PIGR | c.2167A>G p.T723A | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100732520; called by muse, mutect2, varscan2
- PIGU | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as COSV99466482; called by muse, mutect2, varscan2
- PLEK | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs754534773, COSV52251303; called by muse, mutect2, varscan2
- PODXL2 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as rs35388535; called by muse, mutect2, varscan2
- POLR1A | c.99T>G p.I33M | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99807722; called by muse, mutect2, varscan2
- PRPF8 | c.6409C>G p.P2137A | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100025444; called by muse, mutect2, varscan2
- PRPF8 | c.428A>C p.Q143P | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100517520; called by muse, mutect2, varscan2
- PSEN2 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs373392465; called by muse, mutect2, varscan2
- PSPH | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99304283; called by muse, mutect2
- PTP4A2 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV100685693; called by muse, mutect2
- PXDN | c.1789C>T p.R597W | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373022614, COSV99414045; called by muse, mutect2
- RIMS2 | c.2375C>T p.P792L (on ENST00000666250 / NM_001348490.2; = p.P600L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99169776; called by muse, mutect2
- RNF133 | c.692A>G p.Q231R | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100411625; called by muse, mutect2, varscan2
- RNF40 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs564561453, COSV100222111; called by muse, mutect2, varscan2
- RP1 | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99607586; called by muse, mutect2, varscan2
- RPP38 | c.457A>C p.S153R | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100975554; called by muse, mutect2, varscan2
- SACS | c.12193A>T p.I4065F | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs199563625, COSV101207468; called by muse, mutect2, varscan2
- SCAF11 | c.3935A>G p.N1312S | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.13); catalogued as rs1237853967, COSV101014386; called by muse, mutect2, varscan2
- SEC24B | c.3250C>G p.Q1084E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV99493580; called by mutect2, varscan2
- SETBP1 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs779923877, COSV99953410; called by muse, mutect2, varscan2
- SLC4A7 | c.2336T>C p.L779P | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs775266483, COSV99839827; called by muse, mutect2
- SLC6A2 | c.1159G>T p.V387L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV99573915; called by muse, mutect2, varscan2
- SYNE1 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs761189574, COSV55045908; ClinVar: uncertain significance; called by muse, mutect2
- TANGO6 | c.2978G>A p.G993D | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99936247; called by muse, mutect2
- TLCD4 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as COSV100930768; called by muse, mutect2, varscan2
- TMEM132D | c.2089C>G p.Q697E | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.359); catalogued as COSV67159996; called by muse, mutect2, varscan2
- TRPM6 | c.2509G>A p.A837T | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1420546012, COSV100666395; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2176A>G p.I726V | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99511929; called by muse, mutect2, varscan2
- VASH1 | c.7G>C p.G3R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.082); catalogued as COSV99387951; called by muse, mutect2
- VWC2 | c.879G>T p.K293N | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV100514301, COSV61485297; called by muse, mutect2, varscan2
- ZIC1 | c.307C>G p.R103G | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as COSV51551988, COSV99291965; called by muse, mutect2, varscan2
- ZNF536 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100835233, COSV62833010; called by muse, mutect2, varscan2
- ZNF655 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99402161; called by muse, mutect2
- ZNF835 | c.405G>T p.E135D | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV101606356; called by muse, mutect2, varscan2
- ZSCAN4 | c.362A>T p.D121V | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100552509; called by muse, mutect2, varscan2
- AFF2 | c.2762C>A p.P921Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); called by muse, mutect2
- CHD7 | c.3708_3739del p.N1237Ifs*15 | Frame Shift Del (DEL) | VAF 18/112 reads (16%) | called by mutect2, pindel
- FCGBP | c.9086T>C p.F3029S | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.08); called by muse, mutect2
- KRTAP5-1 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MUC2 | c.2468A>G p.K823R | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.48); called by muse, mutect2, varscan2
- NSD1 | c.3767del p.L1256* | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- TARBP2 | c.470dup p.C158Vfs*46 (on ENST00000266987 / NM_134323.2; = p.C137Vfs*46 on NM_004178.4) | Frame Shift Ins (INS) | VAF 17/88 reads (19%) | called by mutect2, pindel, varscan2
- ABCA4 | c.6513C>A p.I2171= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV100933132, COSV64671605; called by muse, mutect2, varscan2
- AHNAK2 | c.5892G>A p.K1964= | Silent (SNP) | VAF 159/522 reads (30%) | catalogued as COSV100317624; called by muse, mutect2, varscan2
- DDO | c.933C>A p.I311= (on ENST00000368924 / NM_001368172.1; = p.I252= on NM_004032.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV64469701; called by muse, mutect2, varscan2
- DPF2 | c.1071C>T p.L357= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV99361678; called by muse, mutect2, varscan2
- FAM155A | c.840A>G p.E280= | Silent (SNP) | VAF 74/150 reads (49%) | catalogued as COSV101028197; called by muse, mutect2, varscan2
- FBLN7 | c.852G>A p.G284= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as COSV99734858; called by muse, mutect2, varscan2
- HECTD1 | c.7530G>A p.K2510= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as COSV101237398; called by muse, mutect2, varscan2
- IL20RA | c.777A>T p.V259= | Silent (SNP) | VAF 50/167 reads (30%) | catalogued as COSV100359991; called by muse, mutect2, varscan2
- PAK3 | c.762G>A p.R254= (on ENST00000262836 / NM_001324328.2; = p.R239= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as rs1420523796, COSV99457464; ClinVar: likely benign; called by muse, mutect2, varscan2
- PAK5 | c.1839G>A p.E613= | Silent (SNP) | VAF 14/181 reads (8%) | catalogued as rs1305569656, COSV100781354; called by muse, mutect2
- RBM33 | c.2067T>C p.N689= | Silent (SNP) | VAF 73/160 reads (46%) | catalogued as COSV100265492; called by muse, mutect2, varscan2
- SLCO1B3 | c.888G>A p.L296= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV99681507; called by muse, mutect2, varscan2
- SLIT2 | c.1011T>C p.S337= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs112603988, COSV99884081; called by muse, mutect2, varscan2
- TRAPPC9 | c.423C>T p.C141= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV101227543, COSV101228496; called by muse, mutect2, varscan2
- TRIM24 | c.2592G>A p.E864= (on ENST00000343526 / NM_015905.3; = p.E830= on NM_003852.4) | Silent (SNP) | VAF 22/189 reads (12%) | catalogued as COSV100630970; called by muse, mutect2
- USP19 | c.1218A>G p.S406= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100026188; called by muse, mutect2, varscan2
